Gene-level copy-number profile of tumor specimen ALCH-B220-TTP1-A from ALCHEMIST case ALCH-B220, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.6 years (19,215 days).
Specimen ALCH-B220-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6bbe3d7e-de0e-454d-b64b-0c996e34b925.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B220-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/992bb50f-bc36-4ff6-b080-306f4a9f9354

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 266; copy number 1: 13,138; copy number 2: 39,921; copy number 3: 4,307; copy number 4: 750; copy number 5: 5; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 266 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,211,340–1,232,067, 2 genes: TNFRSF4, SDF4.
- chr1:16,974,502–17,011,928, 5 genes: MFAP2, AL049569.2, AL049569.1, ATP13A2, AL049569.3.
- chr1:93,278,961–93,279,129, 1 gene (within-gene range 0–1): AL139421.1.
- chr1:112,693,688–112,748,475, 7 genes (within-gene range 0–1): AL603832.1, RHOC, AL603832.3, PPM1J, AL603832.2, TAFA3, NUTF2P4.
- chr2:127,638,381–127,681,786, 2 genes: LIMS2, GPR17.
- chr2:232,343,116–232,548,115, 15 genes (within-gene range 0–2): NRBF2P6, ECEL1P3, AC068134.3, ALPP, AC068134.1, ECEL1P2, ALPG, ECEL1P1, AC068134.2, DIS3L2P1, ALPI, ECEL1, PRSS56, CHRND, CHRNG.
- chr2:241,492,670–241,509,730, 1 gene (within-gene range 0–2): STK25.
- chr5:1,050,384–1,112,063, 2 genes: SLC12A7, MIR4635.
- chr5:135,027,734–135,034,813, 1 gene (within-gene range 0–2): PITX1.
- chr6:133,150,568–133,150,816, 1 gene: MTCYBP4.
- chr7:43,940,895–44,019,175, 6 genes (within-gene range 0–2): POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1.
- chr7:44,013,562–44,019,170, 1 gene (within-gene range 0–2): POLR2J4.
- chr7:66,493,607–66,592,397, 4 genes (within-gene range 0–2): GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3.
- chr7:101,362,875–101,629,296, 4 genes: COL26A1, AC004965.1, LINC01007, MYL10.
- chr7:102,264,706–102,679,295, 31 genes (within-gene range 0–1): AC005088.1, SH2B2, MIR4285, AC091390.1, Y_RNA, PMS2P12, SPDYE6, PRKRIP1, AC091390.3, AC091390.2, MIR548O, AC073517.1, ORAI2, ALKBH4, LRWD1, MIR5090, MIR4467, POLR2J, RASA4B, POLR2J3, UPK3BL2, AC093668.1, SPDYE2, POLR2J3, RASA4, AC105052.4, AC105052.1, UPK3BL1, AC105052.3, SPDYE2B, POLR2J2.
- chr7:129,953,234–130,051,451, 4 genes (within-gene range 0–1): AC073320.1, Y_RNA, ZC3HC1, RNA5SP245.
- chr8:22,089,150–22,141,951, 4 genes: FAM160B2, NUDT18, HR, REEP4.
- chr8:22,165,140–22,232,101, 4 genes (within-gene range 0–1): BMP1, AC105206.1, AC105206.3, PHYHIP.
- chr8:37,784,191–37,844,896, 1 gene (within-gene range 0–1): ADGRA2.
- chr9:19,957,394–22,128,103, 66 genes (broad region; genes not listed).
- chr9:34,546,524–34,546,996, 1 gene: AL160270.2.
- chr9:100,731,240–100,732,355, 1 gene: ACTG1P19.
- chr9:130,120,806–130,501,274, 6 genes (within-gene range 0–2): Y_RNA, GPRACR, NCS1, HMCN2, RN7SL665P, ASS1.
- chr9:130,651,799–130,682,986, 2 genes: AL359092.2, PRDM12.
- chr9:130,892,707–131,123,152, 6 genes: QRFP, FIBCD1, AL161733.1, LAMC3, AL583807.1, AIF1L.
- chr9:137,776,539–138,253,217, 10 genes (within-gene range 0–2): AL590627.1, MIR602, AL772363.1, CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1, FAM157B.
- chr10:100,398,352–100,398,446, 1 gene: Y_RNA.
- chr10:101,226,195–101,229,794, 1 gene (within-gene range 0–2): LBX1.
- chr15:25,178,738–25,268,551, 44 genes (within-gene range 0–1): SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1, SNORD115-45, SNORD115-46, SNORD115-47.
- chr15:41,848,146–41,899,528, 4 genes (within-gene range 0–1): SPTBN5, RNA5SP393, MIR4310, AC020659.1.
- chr15:64,739,891–64,825,668, 3 genes: RBPMS2, MIR1272, PIF1.
- chr16:8,847,650–8,870,032, 5 genes (within-gene range 0–2): AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4.
- chr17:22,406,019–22,413,744, 1 gene: FLJ36000.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–1): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr18:44,214,971–44,579,953, 4 genes (within-gene range 0–1): AC110014.1, LINC01478, KRT8P5, MLECP1.
- chr19:35,523,367–35,545,319, 2 genes (within-gene range 0–1): SBSN, GAPDHS.
- chr21:13,349,265–13,350,648, 1 gene: FGF7P2.
- chr22:20,689,929–20,704,606, 3 genes: POM121L4P, BCRP5, TMEM191A.
- chr22:38,426,327–38,483,447, 3 genes (within-gene range 0–2): KCNJ4, Z97056.3, KDELR3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:22,428,838–22,531,157, 2 genes, copy number 6: ZBTB40, ZBTB40-IT1.
- chr17:77,959,240–78,108,835, 4 genes, copy number 5 (within-gene range 2–5): TNRC6C, AC015804.1, UBE2V2P2, RNU6-625P.

Autosomal genes at a single copy (total copy number 1): 12,798. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
